Somatic mutation profile of tumor specimen TCGA-06-0214-01A (aliquot TCGA-06-0214-01A-02D-1491-08) from TCGA case TCGA-06-0214, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.2 years (24,187 days).
Specimen TCGA-06-0214-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eaeee353-7cdb-4efb-b741-3239a4e8bd35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0214-10A (Blood Derived Normal), aliquot TCGA-06-0214-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6e42df2-7ffd-46ce-955b-afe46a4f3d02

The open-access MAF lists 70 somatic variants for this specimen: 47 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 21, Nonsense Mutation 3, Intron 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDGFRA | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 166/1629 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57265219, COSV57268286, COSV57271923; called by muse, mutect2, varscan2
- ACACB | c.5056C>G p.P1686A | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV58142013; called by muse, mutect2, varscan2
- ACE | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 119/408 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs757694144, COSV52011166, COSV99327631; called by muse, mutect2, varscan2
- ADGRA3 | c.2098G>A p.V700I | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs1387803603, COSV51566510; called by muse, mutect2, varscan2
- ADRM1 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.186); catalogued as rs779806679, COSV53367629, COSV99442640; called by muse, mutect2, varscan2
- ANGEL2 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs771489874, COSV64737240; called by muse, mutect2
- APOB | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51945968; called by muse, mutect2, varscan2
- BTBD9 | c.1559G>T p.C520F | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58432666; called by muse, mutect2, varscan2
- CCL19 | c.197G>A p.R66K | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV100323125, COSV61337539; called by muse, mutect2, varscan2
- CD248 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 90/257 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV60935951; called by muse, mutect2, varscan2
- CFAP20DC | c.602G>A p.R201Q (on ENST00000482387 / NM_001351530.2; = p.R76Q on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as rs778956286, COSV55924982; called by muse, varscan2
- CLIC4 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV65527148; called by muse, mutect2, varscan2
- CROCC | c.1618G>A p.G540R | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV65014023, COSV99070956; called by muse, mutect2
- DIP2B | c.3577C>T p.R1193W | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775940504, COSV56589099; called by muse, mutect2, varscan2
- DNAJA4 | c.757C>G p.Q253E (on ENST00000343789; = p.Q282E on NM_018602.3) | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV59426588; called by muse, mutect2, varscan2
- DSP | c.5379+2T>A p.X1793_splice | Splice Site (SNP) | VAF 14/164 reads (9%) | catalogued as COSV65794426; called by muse, mutect2
- ERCC1 | c.353A>G p.N118S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs749201799, COSV50004985; called by muse, mutect2, varscan2
- FOXN4 | c.597-5C>T | Splice Region (SNP) | VAF 5/25 reads (20%) | catalogued as COSV54497007; called by muse, mutect2, varscan2
- FOXP2 | c.1921G>A p.V641I | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs745987986, COSV63484878; called by muse, mutect2, varscan2
- GBP3 | c.260A>G p.K87R | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV52519372; called by muse, mutect2
- GRM6 | c.1195G>A p.G399S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.522); catalogued as COSV51447555; called by muse, mutect2
- HRNR | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 100/317 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.123); catalogued as rs375817815; called by muse, mutect2, varscan2
- IFT80 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV58450713; called by muse, mutect2
- IL12RB2 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 79/276 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.51); catalogued as rs775778071, COSV52020541; called by muse, mutect2, varscan2
- KSR1 | c.715C>T p.P239S (on ENST00000644974 / NM_001367810.1; = p.P102S on NM_014238.2) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs1159683123, COSV52036873; called by muse, mutect2, varscan2
- KSR2 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV60388681; called by muse, mutect2, varscan2
- LRRC28 | c.866T>A p.L289Q | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV57340502; called by muse, mutect2, varscan2
- MSH6 | c.1354A>G p.M452V | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780734507, COSV52284814; called by muse, mutect2
- MUC16 | c.33266C>A p.T11089N | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as COSV67481909; called by muse, mutect2
- NEPRO | c.36G>A p.W12* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as COSV58724112; called by muse, varscan2
- NF1 | c.5545G>A p.D1849N (on ENST00000358273 / NM_001042492.3; = p.D1828N on NM_000267.3) | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62197537, COSV62213806; called by muse, mutect2, varscan2
- NFIX | c.1408G>A p.A470T (on ENST00000592199 / NM_001365902.3; = p.S420= on NM_002501.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs372257657; called by muse, mutect2
- OR4X2 | c.28T>C p.S10P | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs766317711, COSV56584497; called by muse, mutect2
- OSBP2 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747111711, COSV60243855; called by muse, mutect2, varscan2
- PAM | c.622G>C p.V208L | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV57217349; called by muse, mutect2, varscan2
- PAX5 | c.1037A>G p.Y346C | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1343138367, COSV63910833; called by muse, mutect2, varscan2
- PHOX2B | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56929258; called by muse, mutect2, varscan2
- PLXDC2 | c.1035C>G p.N345K | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV65907092; called by muse, mutect2, varscan2
- PTK2B | c.2590G>A p.A864T | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs753976890, COSV57756767; called by muse, mutect2
- RAD23B | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as COSV63659822; called by muse, mutect2, varscan2
- RRAGA | c.493T>A p.W165R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65843878; called by muse, mutect2, varscan2
- SEC16A | c.4463C>T p.T1488M | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as rs763048548, COSV51536177; called by muse, mutect2, varscan2
- SMTNL1 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV67700504; called by muse, mutect2, varscan2
- SPTA1 | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 110/337 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs747469591, COSV63756424, COSV63761531; called by muse, mutect2, varscan2
- TM7SF3 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58003497; called by muse, mutect2
- USH2A | c.6929C>T p.T2310M | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs151057466; called by muse, mutect2, varscan2
- ZCWPW1 | c.44C>G p.P15R | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV61250080; called by muse, mutect2
- ABCA13 | c.2763C>T p.Y921= | Silent (SNP) | VAF 16/205 reads (8%) | catalogued as rs775129256, COSV70026255; called by muse, mutect2
- AP1AR | c.777G>A p.E259= | Silent (SNP) | VAF 15/164 reads (9%) | catalogued as COSV56770000; called by muse, mutect2
- C12orf57 | c.261C>T p.S87= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV57547352; called by muse, mutect2, varscan2
- CALCOCO2 | c.1089A>G p.S363= | Silent (SNP) | VAF 70/223 reads (31%) | catalogued as rs1159669564, COSV51953101; called by muse, mutect2, varscan2
- CLPTM1 | c.1404C>T p.T468= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV61612627; called by muse, mutect2, varscan2
- EP300 | c.4111C>T p.L1371= | Silent (SNP) | VAF 20/322 reads (6%) | catalogued as COSV54340711; called by muse, mutect2
- GABRA5 | c.1236T>A p.T412= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV59483693; called by muse, mutect2, varscan2
- LENG8 | c.1758C>A p.V586= | Silent (SNP) | VAF 11/242 reads (5%) | catalogued as COSV58725840, COSV58729500; called by muse, mutect2
- LYST | c.5418C>T p.H1806= | Silent (SNP) | VAF 12/185 reads (6%) | catalogued as rs146990900; ClinVar: likely benign; called by muse, mutect2
- MKRN3 | c.564C>T p.D188= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV58811380; called by muse, mutect2, varscan2
- PCLO | c.8682T>C p.D2894= | Silent (SNP) | VAF 97/435 reads (22%) | catalogued as COSV61654959; called by muse, mutect2, varscan2
- PITPNA | c.78G>A p.V26= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as COSV57935597; called by muse, mutect2, varscan2
- SEMA4F | c.756G>A p.T252= | Silent (SNP) | VAF 70/250 reads (28%) | catalogued as rs897613198, COSV60284654; called by muse, mutect2, varscan2
- SGMS2 | c.558C>T p.F186= | Silent (SNP) | VAF 38/247 reads (15%) | catalogued as rs150340532; called by muse, mutect2, varscan2
- SLC38A10 | c.2622C>G p.L874= | Silent (SNP) | VAF 24/246 reads (10%) | catalogued as COSV55848027; called by muse, mutect2
- SYDE2 | c.3366C>T p.I1122= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs371604572; called by muse, mutect2, varscan2
- TEX15 | c.555C>T p.S185= (on ENST00000256246; = p.S568= on NM_001350162.2) | Silent (SNP) | VAF 44/153 reads (29%) | catalogued as rs755831106, COSV56349906, COSV56350750; called by muse, mutect2, varscan2
- TMEM268 | c.534G>A p.R178= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as COSV55987161; called by muse, mutect2, varscan2
- TSHZ2 | c.2370C>T p.H790= | Silent (SNP) | VAF 65/199 reads (33%) | catalogued as rs138612067; called by muse, mutect2, varscan2
- WDR91 | c.1593C>A p.G531= | Silent (SNP) | VAF 33/159 reads (21%) | catalogued as COSV60371339; called by muse, mutect2, varscan2
- ZNF552 | c.1215G>A p.K405= | Silent (SNP) | VAF 59/198 reads (30%) | catalogued as rs1258665970, COSV66971849; called by muse, mutect2, varscan2
- BCL7A | c.561+31C>T | Intron (SNP) | VAF 63/198 reads (32%) | called by muse, mutect2, varscan2
- PRR12 | c.51+538C>T | Intron (SNP) | VAF 49/132 reads (37%) | catalogued as rs1268459721, COSV69819307; called by muse, mutect2, varscan2
